Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UN, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UN-01A (Primary Tumor).

[page 1 of 4]
Print Malignancy History		

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

PTC positive FNA left lobe 1.2c, thyroid.

Specimens Submitted:

- 1: Delphian lymph node (fs)
- 2: Left lower parathyroid, rule out (fs)
- 3: Left paratracheal tissue (fs)
- 4: Total thyroidectomy
- 5: Pretracheal tissue

DIAGNOSIS:

1. Delphian lymph node (fs):
Part # 1
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1
2. Left lower parathyroid, rule out (fs), biopsy:
- Benign parathyroid tissue
3. Left paratracheal tissue (fs), biopsy:
- Benign parathyroid tissue
4. Total thyroidectomy:
Part # 4
Tumor Type:
Papillary carcinoma, classical type
Histologic Grade:
Well differentiated
Mitotic Activity:
Not identified
Tumor Necrosis:
Not identified
Tumor Location:
Left lobe
Tumor Size:
Greatest diameter is 1.2 cm.
Tumor Encapsulation:
Completely surrounded

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

5-2-12 RD

[page 2 of 4]
Capsular Invasion:
Focal invasion
Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Two foci of papillary microcarcinoma left lobe (0.1cm) and right lobe (0.2cm)

Adenoma(s) (away from the carcinoma):
Not identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:
Not identified

Lymph Nodes:
Two benign peri-thyroidal lymph nodes.

5. Pretracheal tissue:
- Benign fibroadipose tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "Delphian lymph node" and consists of a single tan firm lymph node measuring 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2. The specimen is received fresh for frozen section consultation, labeled "Left lower parathyroid, rule out" and consists of a single tan soft tissue fragment measuring 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

3. The specimen is received fresh for frozen section consultation, labeled "Left paratracheal tissue" and consists of a single tan soft tissue fragment measuring 2.0 x 0.6 x 0.5 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

[page 3 of 4]
4). The specimen is received fresh and placed in formalin, labeled "Total thyroidectomy, stitch marks left lobe of thyroid " and consists of a thyroid weighing 15 g after fixation. The right lobe measures 4 x 2.5 x 0.8 cm , the left lobe measures 4 x 2.5 x 1.2 cm and the isthmus measures 2 x 0.5 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning the left lobe reveals a 1 x 1 x 0.9 cm white-tan nodule. Sections through the remaining tissue is unremarkable. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen was submitted for and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule, left lobe
LL - left lobe
RL - right lobe
IS - isthmus

5). The specimen is received in formalin, labeled " pretracheal tissue " and consists of a 1 x 0.4 x 0.2 cm fragment of tan soft tissue. Entirely submitted in toto.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Delphian lymph node (fs)

Block	Sect. Site	PCs
1	FSC	2

Part 2: Left lower parathyroid, rule out (fs)

Block	Sect. Site	PCs
1	FSC	2

Part 3: Left paratracheal tissue (fs)

Block	Sect. Site	PCs
1	FSC	2

Part 4: Total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
4	LL	4
5	N	5
5	RL	5

Part 5: Pretracheal tissue

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Delphian lymph node (fs): Benign lymph node
Permanent diagnosis: same
2. Frozen section diagnosis: Left lower parathyroid, rule out (fs): Consistent with parathyroid tissue,

[page 4 of 4]
Permanent diagnosis: same

3. Frozen section diagnosis: Left paratracheal tissue (fs): Consistent with parathyroid tissue
Permanent diagnosis: same

Source: NCI Genomic Data Commons file 77fe9770-56d1-4dde-bd10-a242604d33a6 (TCGA-DJ-A3UN.F69B781C-1912-4E31-8303-EAB84A84F9AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).